Somatic mutation profile of tumor specimen TARGET-20-PATDRB-09A (aliquot TARGET-20-PATDRB-09A-01D) from TARGET case TARGET-20-PATDRB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.1 years (5,865 days).
Specimen TARGET-20-PATDRB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e049480-ce5d-4507-a74d-8ea5ba12eb60.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATDRB-14A (Bone Marrow Normal), aliquot TARGET-20-PATDRB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1e8a8a3-b662-4a50-8257-5999cf678896

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 35/361 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEBPA | c.928del p.T310Rfs*8 | Frame Shift Del (DEL) | VAF 64/206 reads (31%) | catalogued as COSV57199146; called by mutect2, pindel*
- GATA2 | c.962T>A p.L321H | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62003239, COSV62003719, COSV62003772; called by muse, varscan2
- GATA2 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62003029, COSV62003510, COSV62004917; called by muse, varscan2
- PTPRH | c.3070G>A p.V1024M | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766566365, COSV54747364; called by muse, mutect2, varscan2
- CEBPA | c.260dup p.Q88Afs*20 | Frame Shift Ins (INS) | VAF 11/31 reads (35%) | called by mutect2, varscan2
